Surgical pathology report (de-identified scan), TCGA case TCGA-28-1756, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-1756-01C (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

- A. BRAIN, RIGHT TEMPORAL, BIOPSY:**
- Glioblastoma multiforme, WHO grade IV
- B. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:**
- Glioblastoma multiforme, WHO grade IV
- C. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #1:**
- Glioblastoma multiforme, WHO grade IV
- 0% of necrosis
- 80% of tumor cellularity
- D. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #2:**
- Glioblastoma multiforme, WHO grade IV
- 0% of necrosis
- 70% of tumor cellularity
- E. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #3:**
- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 70% of tumor cellularity
- F. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #4:**
- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 60% of tumor cellularity
- G. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #5:**
- Glioblastoma multiforme, WHO grade IV
- 0% of necrosis
- 90% of tumor cellularity
- H. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:**
- Glioblastoma multiforme, WHO grade IV
- I. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #6:**
- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis

Patient Case(s): [REDACTED]

[page 2 of 7]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

PATH #: [REDACTED]

- 70% of tumor cellularity

J. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #7:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 60% of tumor cellularity

K. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #8:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

L. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #9:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

M. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #10:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

N. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar [REDACTED]. Hence, the low 5% result in this case suggests a likelihood of this tumor being responsive to Temodar.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas [REDACTED]. Molecular subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell. [REDACTED]

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas. [REDACTED] between laminin-8 and glial tumor grade, recurrence, and patient survival. [REDACTED]

Accordingly, elevated expression of $\beta 1$ and $\beta 2$ in this tumor suggest the tumor aggressiveness intermediate between the $\beta 1 \downarrow$ (or normal)/ $\beta 2$ normal (or $\uparrow$) (the most favorable prognosis) and $\beta 1 \uparrow$ / $\beta 2 \downarrow$ (least favorable prognosis).

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) has been shown to be associated with a relative resistance of glioblastoma multiforme to radiation therapy.

[REDACTED] Prognostic Associations of Activated Mitogen-Activated Protein Kinase and Akt Pathways in Glioblastoma. Clin Cancer Res. [REDACTED]

Correspondingly, presence of a large fraction of cells immunonegative to pMAPK antibody in this case suggests a likelihood of this tumor being responsive to radiation therapy.

[page 3 of 7]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

PATH #: [REDACTED]

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

IDC2a: Selected slides were reviewed in consultation with [REDACTED]

HISTORY: None given

MICROSCOPIC:

Sections disclose predominantly cortex and underlying white matter with moderately cellular proliferation of highly pleomorphic hyperchromatic elongate nuclei often containing multinucleated/cleft forms. Scattered mitotic figures are seen. Incipient endothelial proliferation is present on multiple slides but there is no necrosis. The tumor has features of secondary GBM given the strong p53 expression, low mitotic and Ki-67 count, only incipient endothelial proliferation and only minimal up-regulation of laminin beta 1.

IMMUNOSTAINS:

P53 (M1): Strong diffuse positivity in up to 100% of tumor nuclei

Ki-67 (M1): Up to 8%

MGMT (M1): Up to 5%

PTEN (M1): Loss (1+ in 70% of tumor cells)

pMAPK (M1): Up to 20% of tumor nuclei are positive and up to 25% of tumor cell cytoplasm is positive

Laminin beta-1 (8/411) (M1): Minimal upregulation (2+ in endothelial cells)

Laminin beta-2 (9/421) (M1): Slight upregulation (1-2+ in endothelial cells)

GROSS:

A. RIGHT TEMPORAL

Labeled with the patient's name, labeled "right temporal mass", and received fresh for intraoperative consultation and subsequently submitted in formalin are two portions of soft pale tan cortical tissue with adherent blood clot measuring 1.6 and 1.7 cm in greatest dimension and amounting in aggregate to 2.1 x 1.7 x 0.4 cm. Entirely submitted.

Slide key:

A1. Frozen remnant - 1

A2. Remaining tissue - 2

B. RIGHT TEMPORAL

Labeled with the patient's name, labeled "right temporal", and received fresh for intraoperative consultation and subsequently submitted in formalin is a 1.1 x 0.7 x 0.2 cm aggregate of soft pale tan cortical tissue ranging from 0.2 to 0.7 cm in greatest dimension. Entirely submitted.

Slide key:

B1. Frozen remnant - 2

B2. Remaining tissue - multiple

C. RIGHT TEMPORAL NCI #1

Labeled with the patient's name, labeled "right temporal C", and received fresh and subsequently submitted in formalin is a 1.1 x 0.5 x 0.2 cm portion of soft pale tan cortical tissue with areas of hemorrhage.

Entirely submitted.

Slide key:

[page 4 of 7]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

PATH #: [REDACTED]

CI. 1

D. RIGHT TEMPORAL NCI #2

Labeled with the patient's name, labeled "right temporal D", and received fresh and subsequently submitted in formalin is a 1.0 x 0.9 x 0.2 portion of soft pale tan cortical tissue with areas of hemorrhage. Entirely submitted.

D1. 1

E. RIGHT TEMPORAL NCI #3

Labeled with the patient's name, labeled "right temporal E", and received fresh and subsequently submitted in formalin is a 0.6 x 0.4 x 0.2 cm portion of soft pale tan cortical tissue with areas of hemorrhage. Entirely submitted.

E1. 1

F. RIGHT TEMPORAL NCI #4

Labeled with the patient's name, labeled "right temporal F", and received fresh and subsequently submitted in formalin is a 1.1 x 0.6 x 0.2 cm soft pale tan portion of cortical tissue with areas of hemorrhage. Entirely submitted.

F1. 1

G. RIGHT TEMPORAL NCI #5

Labeled with the patient's name, labeled "right temporal G", and received fresh and subsequently submitted in formalin is a 1.0 x 0.9 x 0.3 cm portion of soft pale tan cortical tissue with areas of hemorrhage. Entirely submitted.

G1. 1

H. RIGHT TEMPORAL/PERMANENT

Labeled with the patient's name, labeled "right temporal", and received in formalin is a 1.1 x 0.7 x 0.5 cm portion of soft pale tan cortical tissue with adherent blood clot. Entirely submitted.

H1. 4

I. RIGHT TEMPORAL NCI #6

Labeled with the patient's name, labeled "right temporal NCI #6", and received fresh and subsequently submitted in formalin is a 0.6 x 0.4 x 0.2 cm portion of soft cortical tissue with areas of hemorrhage. Entirely submitted.

I1. 1

J. RIGHT TEMPORAL NCI #7

Labeled with the patient's name, labeled "right temporal #7 J", and received fresh and subsequently submitted in formalin is a 0.6 x 0.4 x 0.2 cm portion of soft pale tan cortical tissue with areas of hemorrhage. Entirely submitted.

J1. 1

K. RIGHT TEMPORAL NCI #8

Labeled with the patient's name, labeled "right temporal NCI #8 K", and received fresh and subsequently submitted in formalin is a 1.5 x 1.1 x 0.2 cm portion of soft pale tan cortical tissue with areas of hemorrhage. Entirely submitted.

K1. 1

L. RIGHT TEMPORAL NCI #9

Labeled with the patient's name, labeled "right temporal NCI #9 L", and received fresh and subsequently submitted in formalin is a 0.9 x 0.6 x 0.2 cm portion of soft pale tan cortical tissue with areas of hemorrhage. Entirely submitted.

L1. 1

M. RIGHT TEMPORAL NCI #10

Labeled with the patient's name, labeled "right temporal NCI #10 M", and received fresh and subsequently submitted in formalin is a 1.6 x 1.2 x 0.3 cm aggregate of soft pale tan cortical tissue with areas of hemorrhage. Entirely submitted.

[page 5 of 7]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

PATH #: [REDACTED]

M1. Multiple

N. TEMPORAL LOBE

Labeled with the patient's name, labeled "temporal lobe", and received in formalin is a 3.1 x 2.2 x 0.6 cm aggregate of soft, tan-gray cortical tissue with areas of hemorrhage. Serially sectioned to reveal soft, gray-brown hemorrhagic tissues. Entirely submitted.

N1, N2. 4 each

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

A. RIGHT TEMPORAL FS:

- Glioma, low cellularity

B. RIGHT TEMPORAL FS

- Astrocytoma, at least anaplastic

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED] Center Department of Pathology and Laboratory Medicine. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

[page 6 of 7]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

PATH #: [REDACTED]

FISH (FLUORESCENCE IN SITU HYBRIDIZATION) for EGFR

RESULTS:

Number of cells analyzed: 40

Ratio of EGFR/CEP: 1.3

Percentage of cells with ≥ 4 copies of EGFR: 62.5%

Amplification: YES

High Level of Polysomy: YES

INTERPRETATION:

1. Samples are interpreted as Positive if :
- a. EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells.
- b. When high level of polysomy ($\geq$ four copies of EGFR in $\geq 40\%$ of cells) is present.
2. Samples are interpreted as Negative if EGFR to CEP 7 signal ratio is < 2.0 or in the absence of high level of polysomy ($\geq$ four copies of EGFR).
3. Samples are considered inconclusive, requiring consult with the pathologist, when EGFR to CEP 7 signal ratio is ≥ 2.0 in $< 10\%$ of analyzed cells or when high level of polysomy ($\geq$ four copies of EGFR) is present in $< 40\%$ of cells. These cases also need to be co-read.

REFERENCES

[REDACTED]

[page 7 of 7]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

PATH #: [REDACTED]

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Source: NCI Genomic Data Commons file 0ac921ce-92d5-4e45-b0c0-e2e8c9afe458 (TCGA-28-1756.952E887B-A9BC-4DED-8919-443BD5F4AA71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).